Somatic mutation profile of tumor specimen TCGA-DV-A4W0-01A (aliquot TCGA-DV-A4W0-01A-11D-A25V-10) from TCGA case TCGA-DV-A4W0, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 55.0 years (20,101 days).
Specimen TCGA-DV-A4W0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa8ed943-6bf2-4f9f-bc86-5b164da8bd8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DV-A4W0-10A (Blood Derived Normal), aliquot TCGA-DV-A4W0-10A-01D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f22cecba-2f53-4d8d-be7e-c6a675249b73

The open-access MAF lists 70 somatic variants for this specimen: 57 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 12, Frame Shift Del 11, Nonsense Mutation 4, Frame Shift Ins 1, Splice Site 1, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC008397.2 | c.1877C>T p.T626M | Missense Mutation (SNP) | VAF 87/293 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1249529810, COSV99441226; called by muse, mutect2, varscan2
- AKR1A1 | c.352T>A p.F118I | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100698748; called by muse, varscan2
- ANGPTL8 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as rs759926768, COSV99371039; called by mutect2, varscan2
- ARID1A | c.1994G>C p.G665A | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV100252209; called by muse, mutect2, varscan2
- BAP1 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV56240393, COSV99964331; called by muse, mutect2, varscan2
- BRD3 | c.1622A>T p.N541I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as COSV100325250; called by muse, mutect2
- CEP164 | c.3745A>G p.R1249G | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs201233959, COSV99633687; called by muse, mutect2, varscan2
- CHD9 | c.2326G>C p.D776H | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99529313; called by muse, mutect2, varscan2
- CHPF | c.1241T>A p.L414Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99705067; called by muse, mutect2, varscan2
- CNGA2 | c.1054T>C p.F352L | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100323785; called by muse, mutect2, varscan2
- CNR2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs199631465, COSV65692640; called by muse, mutect2, varscan2
- DAP3 | c.712G>T p.D238Y | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100546573; called by muse, mutect2, varscan2
- DNAH9 | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.158); catalogued as rs756842427, COSV52375746; called by muse, mutect2, varscan2
- DNAH9 | c.10208A>T p.D3403V | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV99306474; called by muse, mutect2, varscan2
- EXOC4 | c.2753T>A p.V918E | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV99554459; called by muse, mutect2
- FAM53B | c.226A>T p.S76C | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV99784971; called by muse, mutect2, varscan2
- FAT1 | c.3655G>T p.D1219Y | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101499427; called by muse, mutect2, varscan2
- FBN2 | c.3452T>C p.M1151T | Missense Mutation (SNP) | VAF 102/271 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99328569; called by muse, varscan2
- FSD2 | c.1849C>G p.P617A | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100575186; called by muse, mutect2, varscan2
- GPX4 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100684716; called by muse, mutect2, varscan2
- GRIN2A | c.1692G>A p.M564I | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV100410268; called by muse, mutect2, varscan2
- HUNK | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as rs534370710, COSV54227833; called by muse, mutect2, varscan2
- IRX6 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV51859859, COSV99306412; called by muse, mutect2, varscan2
- ITGB4 | c.2993A>C p.E998A | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV99564254; called by muse, mutect2, varscan2
- KARS1 | c.883T>C p.Y295H | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100094235; called by muse, mutect2, varscan2
- MSTN | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99640719; called by muse, mutect2, varscan2
- MYBPC3 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397515887, CM102043, COSV99920503, COSV99920566; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAALAD2 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.422); catalogued as COSV100428566; called by muse, mutect2, varscan2
- NPVF | c.36G>T p.L12F | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.909); catalogued as COSV99760266; called by muse, mutect2, varscan2
- PAMR1 | c.462T>G p.I154M | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99552811; called by muse, mutect2, varscan2
- PBRM1 | c.3028C>T p.R1010* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV56258855; called by muse, mutect2, varscan2
- POU6F2 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101302741; called by muse, mutect2, varscan2
- PRKCSH | c.447G>C p.K149N | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs1276408489, COSV99371702; called by muse, mutect2, varscan2
- PRPF38A | c.874A>T p.S292C | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV99933333; called by muse, mutect2, varscan2
- PTPRT | c.1318G>T p.V440F | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV100628395, COSV100628864; called by muse, varscan2
- RAD9B | c.739A>T p.I247L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV100799382; called by muse, mutect2
- RAD9B | c.740T>G p.I247R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100799383; called by muse, mutect2
- RIMKLB | c.571C>A p.L191M | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.761); catalogued as COSV100223964; called by muse, mutect2, varscan2
- RNF157 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as COSV99487123; called by muse, mutect2, varscan2
- RTEL1 | c.2655G>A p.E885= | Splice Region (SNP) | VAF 21/79 reads (27%) | catalogued as rs979303111, COSV100542513; called by muse, mutect2, varscan2
- SIPA1 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 40/136 reads (29%) | catalogued as COSV101255862; called by muse, mutect2, varscan2
- TLK2 | c.1618T>A p.F540I (on ENST00000326270 / NM_001284333.2; = p.F518I on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100409310; called by muse, mutect2, varscan2
- XPO6 | c.3277-1G>A p.X1093_splice | Splice Site (SNP) | VAF 26/115 reads (23%) | catalogued as COSV100485137; called by muse, mutect2, varscan2
- ZNF680 | c.684T>A p.H228Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100549228; called by muse, mutect2, varscan2
- AGL | c.2449dup p.I817Nfs*3 | Frame Shift Ins (INS) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- DCDC2B | c.432del p.F144Lfs*3 | Frame Shift Del (DEL) | VAF 68/248 reads (27%) | called by mutect2, varscan2
- DHX9 | c.1775del p.K592Rfs*19 | Frame Shift Del (DEL) | VAF 24/93 reads (26%) | called by mutect2, pindel, varscan2
- DRG2 | c.153del p.G52Efs*7 | Frame Shift Del (DEL) | VAF 81/320 reads (25%) | called by pindel, varscan2
- EZR | c.558_561del p.N186Kfs*6 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- LARP4 | c.1046del p.N349Mfs*16 | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | called by mutect2, pindel
- PGAM2 | c.65del p.F22Sfs*9 | Frame Shift Del (DEL) | VAF 27/122 reads (22%) | called by mutect2, varscan2
- RNF139 | c.1217del p.L406Pfs*11 | Frame Shift Del (DEL) | VAF 20/91 reads (22%) | called by mutect2, pindel, varscan2
- RTTN | c.2791_2802del p.S931_F934del | In Frame Del (DEL) | VAF 12/79 reads (15%) | called by mutect2, pindel
- SOS1 | c.3165del p.L1056Cfs*32 | Frame Shift Del (DEL) | VAF 50/165 reads (30%) | called by mutect2, pindel, varscan2
- UBTF | c.715del p.D239Tfs*5 | Frame Shift Del (DEL) | VAF 28/131 reads (21%) | called by mutect2, pindel, varscan2
- WDR45B | c.844del p.S282Pfs*56 | Frame Shift Del (DEL) | VAF 36/147 reads (24%) | called by mutect2, pindel, varscan2
- ZNF543 | c.245del p.D82Afs*27 | Frame Shift Del (DEL) | VAF 22/91 reads (24%) | called by mutect2, pindel, varscan2
- DNAH3 | c.7852C>A p.R2618= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs374594409, COSV54506757; called by muse, mutect2, varscan2
- DNAH9 | c.5193G>T p.V1731= | Silent (SNP) | VAF 28/141 reads (20%) | catalogued as COSV99306472; called by muse, mutect2, varscan2
- ERN2 | c.2763T>A p.P921= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV99891752; called by muse, mutect2, varscan2
- LAMA2 | c.2688G>A p.R896= | Silent (SNP) | VAF 55/204 reads (27%) | catalogued as COSV101370597; called by muse, varscan2
- MGAM | c.4542C>A p.P1514= | Silent (SNP) | VAF 66/198 reads (33%) | catalogued as COSV101527555, COSV72075395; called by muse, mutect2, varscan2
- POLR1A | c.42C>A p.G14= | Silent (SNP) | VAF 34/138 reads (25%) | catalogued as COSV99606416; called by muse, mutect2, varscan2
- PTGFRN | c.2100A>G p.S700= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as COSV101277395; called by muse, mutect2, varscan2
- RYR1 | c.13866C>T p.G4622= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as rs370369058, COSV62097189; called by muse, mutect2, varscan2
- SLC13A5 | c.342C>G p.L114= | Silent (SNP) | VAF 53/179 reads (30%) | catalogued as COSV99546001; called by muse, mutect2, varscan2
- SLC4A10 | c.1461T>A p.I487= (on ENST00000446997 / NM_001354461.2; = p.I457= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99764675; called by muse, mutect2, varscan2
- TBC1D31 | c.1392G>A p.K464= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV99782891; called by muse, mutect2, varscan2
- VSTM4 | c.306G>A p.L102= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as COSV100039405; called by muse, mutect2, varscan2
- OSGIN1 | n.1178C>T | RNA (SNP) | VAF 34/185 reads (18%) | catalogued as rs371987625; called by muse, mutect2, varscan2
